Gene-level copy-number profile of tumor specimen TCGA-SR-A6MZ-01A from TCGA case TCGA-SR-A6MZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.0 years (16,802 days).
Specimen TCGA-SR-A6MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.51829654-cdbb-4921-9a16-8f59f51be7a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SR-A6MZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0c3b644-82ea-42bb-845a-f4d8defd9825

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,263; copy number 2: 38,396; copy number 3: 14,160; copy number 4: 1,995; copy number 5: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SR-A6MZ-01A-11D-A35H-01): tumor purity 0.56, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:23,243,637–23,484,971, 6 genes, copy number 5 (within-gene range 3–5): CHMP7, R3HCC1, LOXL2, AC090197.1, ENTPD4, AC104561.1.

Autosomal genes at a single copy (total copy number 1): 5,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
